Gene-level copy-number profile of specimen HCM-CSHL-0586-C32-85D from HCMI case HCM-CSHL-0586-C32, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0586-C32-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 44286504-3c2f-49b6-99f8-f68437c02500.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0586-C32-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,738 have no estimate.
https://portal.gdc.cancer.gov/files/442b3f66-9fad-4016-bd45-05509d59ac37

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 39; copy number 2: 7,890; copy number 3: 12,960; copy number 4: 29,894; copy number 5: 3,430; copy number 6: 3,458; copy number 7: 494; copy number 8: 410; copy number 9: 39; copy number 10: 2; copy number 11: 66; copy number 12: 40; copy number 13: 8; copy number 14: 17; copy number 16: 69; copy number 17: 6; copy number 25: 1; copy number 27: 3; copy number 28: 20; copy number 29: 10; copy number 31: 10; copy number 37: 11.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–4): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 302 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:137,682–195,411, 8 genes, copy number 13: AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2.
- chr9:1,977,784–16,870,843, 181 genes, copy number 9–37 (within-gene range 5–57) (broad region; genes not listed).
- chr9:41,974,362–41,983,753, 2 genes, copy number 10: RBM17P3, CR788268.1.
- chr17:26,981,694–27,649,560, 23 genes, copy number 9: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1, AC015688.4, AC015688.6, LGALS9.
- chr17:74,584,679–75,708,062, 63 genes, copy number 12–16 (within-gene range 8–16) (broad region; genes not listed).
- chr19:14,091,688–14,612,035, 25 genes, copy number 11–14: PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1, RN7SL231P, AC011509.2, AC011509.1, LINC01841, LINC01842, ADGRE5, AC008569.1, DDX39A, PKN1, AC008569.2, PTGER1, GIPC1, SNRPGP15, DNAJB1, TECR, MIR639, NDUFB7, CLEC17A, RN7SL337P, RN7SL842P.

Autosomal genes at a single copy (total copy number 1): 39. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
